Somatic mutation profile of tumor specimen TARGET-10-PARDKG-09A (aliquot TARGET-10-PARDKG-09A-01D) from TARGET case TARGET-10-PARDKG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.8 years (3,592 days).
Specimen TARGET-10-PARDKG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46ea9c88-9e89-4c7d-aabb-10cd9360f86f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDKG-10A (Blood Derived Normal), aliquot TARGET-10-PARDKG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef005185-3e2e-43d9-9825-fef35648f4b9

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, Intron 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2624C>A p.T875N | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1057520016, COSV67598981; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AKR1B15 | c.257C>A p.A86D | Missense Mutation (SNP) | VAF 77/175 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as COSV71152708; called by muse, mutect2, varscan2
- DCAF8L1 | c.39C>A p.D13E | Missense Mutation (SNP) | VAF 56/63 reads (89%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV71595102; called by muse, mutect2, varscan2
- IGHV3-38 | c.289T>C p.Y97H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.282); catalogued as rs78660098; called by muse, mutect2
- SHROOM2 | c.3265G>A p.V1089I | Missense Mutation (SNP) | VAF 58/65 reads (89%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs761979111; called by muse, mutect2, varscan2
- TMC2 | c.995G>A p.W332* | Nonsense Mutation (SNP) | VAF 34/65 reads (52%) | catalogued as rs1240401250, COSV62654311; called by muse, mutect2, varscan2
- ANK3 | c.2729G>C p.R910P (on ENST00000280772 / NM_001320874.2; = p.R44P on NM_001149.3) | Missense Mutation (SNP) | VAF 78/193 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DDX6 | c.1194_1199del p.D399_I400del | In Frame Del (DEL) | VAF 10/60 reads (17%) | called by mutect2, pindel, varscan2
- CBX3 | c.6C>T p.A2= | Silent (SNP) | VAF 21/31 reads (68%) | catalogued as rs953761509; called by muse, mutect2, varscan2
- PANK4 | c.1743C>T p.D581= | Silent (SNP) | VAF 47/107 reads (44%) | catalogued as rs763196618, COSV65865722; called by muse, mutect2, varscan2
- RASSF10 | c.1413C>T p.A471= | Silent (SNP) | VAF 59/133 reads (44%) | called by muse, mutect2, varscan2
- TTN | c.23052A>T p.S7684= (on ENST00000591111; = p.S6757= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/191 reads (32%) | called by muse, mutect2, varscan2
- BTNL9 | c.929-200C>T | Intron (SNP) | VAF 23/159 reads (14%) | called by muse, mutect2, varscan2
